Somatic mutation profile of tumor specimen TCGA-EE-A2GL-06A (aliquot TCGA-EE-A2GL-06A-11D-A196-08) from TCGA case TCGA-EE-A2GL, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 43.9 years (16,043 days).
Specimen TCGA-EE-A2GL-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1314850-ab58-443e-bc61-d1879f2e10c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2GL-10A (Blood Derived Normal), aliquot TCGA-EE-A2GL-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d25141d6-e11c-4221-bc94-7c41a9c255c7

The open-access MAF lists 414 somatic variants for this specimen: 258 protein-altering or splice-affecting, 143 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 234, Silent 143, Nonsense Mutation 14, RNA 7, Splice Site 5, Splice Region 2, Intron 2, 5'Flank 2, Frame Shift Del 2, 3'UTR 1, In Frame Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 76/245 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PDGFRA | c.704G>C p.C235S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57264163, COSV57266901, COSV57267810; called by muse, mutect2, varscan2
- ABCA12 | c.1301G>A p.R434Q (on ENST00000272895 / NM_173076.3; = p.R116Q on NM_015657.3) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs745415552, COSV55947973; called by mutect2, varscan2
- ABCB5 | c.1760G>A p.R587Q (on ENST00000404938 / NM_001163941.2; = p.R142Q on NM_178559.6) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs755832012, COSV51702431; called by muse, mutect2, varscan2
- ACSBG1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768536234, COSV51903023; called by muse, mutect2, varscan2
- ADAM18 | c.2203G>A p.D735N | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs184662370, COSV55843220; called by muse, mutect2, varscan2
- ADARB1 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV62341554; called by muse, mutect2, varscan2
- ADGRG7 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs779095865, COSV56293281; called by mutect2, varscan2
- ADH1B | c.728A>G p.N243S | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as rs1296256442, COSV59294918; called by muse, mutect2
- ADH1C | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.336); catalogued as COSV72463369; called by muse, mutect2, varscan2
- AFF4 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV54791009; called by muse, mutect2, varscan2
- AL645922.1 | c.3436G>A p.E1146K | Missense Mutation (SNP) | VAF 37/422 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.849); catalogued as COSV64886962; called by muse, mutect2
- ALDH4A1 | c.1574C>G p.A525G | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.216); catalogued as COSV51889786; called by muse, mutect2, varscan2
- AMIGO1 | c.503A>T p.N168I | Missense Mutation (SNP) | VAF 23/281 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100881000; called by muse, mutect2
- ANKRA2 | c.164T>G p.I55R | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV57140388; called by muse, mutect2, varscan2
- APOB | c.11609C>T p.S3870F | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.373); catalogued as rs1443211459, COSV51921506; called by muse, mutect2, varscan2
- ARAP1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 24/339 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.167); catalogued as COSV61989144; called by muse, mutect2
- ARAP2 | c.4883G>A p.R1628Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.223); catalogued as rs771641324, COSV58281935, COSV58289114; called by mutect2, varscan2
- ASH1L | c.6232C>T p.R2078C (on ENST00000368346 / NM_001366177.2; = p.R2073C on NM_018489.3) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs772388982, COSV64204956; called by mutect2, varscan2
- ASXL3 | c.3653C>T p.S1218L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.194); catalogued as rs780764559, COSV52455959; called by muse, mutect2, varscan2
- ATP2A3 | c.2326T>G p.F776V | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV59225653; called by muse, mutect2
- ATP6V0A4 | c.1189A>C p.T397P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59472142; called by muse, mutect2, varscan2
- B3GAT3 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV53881216; called by muse, mutect2, varscan2
- BCOR | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV60698413; called by muse, mutect2
- BICC1 | c.2371T>C p.Y791H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.355); catalogued as COSV54061638; called by muse, mutect2, varscan2
- BLK | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV52049064; called by muse, mutect2
- BLK | c.1181-1G>A p.X394_splice | Splice Site (SNP) | VAF 10/96 reads (10%) | catalogued as rs922956428, COSV52054576; called by muse, mutect2
- BLK | c.1181G>A p.G394E | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99377043; called by muse, mutect2
- BMPER | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51810630; called by muse, mutect2, varscan2
- BMT2 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV51774329; called by muse, mutect2, varscan2
- BPIFB6 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV62754076; called by muse, mutect2, varscan2
- C19orf57 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.391); catalogued as COSV60967039; called by muse, mutect2, varscan2
- CACNA1G | c.5290C>T p.L1764F | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61719795; called by muse, mutect2
- CADPS | c.4057G>A p.D1353N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as rs777645997, COSV51865517; called by mutect2, varscan2
- CALML5 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV66702330; called by muse, mutect2
- CAMK1G | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV50520143; called by muse, mutect2, varscan2
- CAMK1G | c.1325A>C p.K442T | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.831); catalogued as COSV50520146; called by muse, mutect2, varscan2
- CAPN13 | c.1954G>A p.G652R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.545); catalogued as COSV54427982; called by muse, mutect2, varscan2
- CAST | c.260C>T p.S87L (on ENST00000341926; = p.S170L on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV57781810; called by muse, mutect2, varscan2
- CBLB | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.996); catalogued as rs573417053, COSV51420594; called by mutect2, varscan2
- CCDC110 | c.1601T>C p.L534S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.714); catalogued as rs759313082, COSV56869077; called by mutect2, varscan2
- CCDC33 | c.2051G>A p.G684E | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as COSV51430419; called by muse, mutect2, varscan2
- CCDC88A | c.3401C>T p.S1134F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV55055598; called by muse, mutect2, varscan2
- CCNE2 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 85/340 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57374861; called by muse, mutect2, varscan2
- CD1C | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV63805564; called by muse, mutect2, varscan2
- CD200R1L | c.430+1G>A p.X144_splice | Splice Site (SNP) | VAF 5/47 reads (11%) | catalogued as COSV68003708; called by muse, mutect2, varscan2
- CD5L | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63820957; called by muse, mutect2
- CDH18 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV56898154; called by muse, mutect2, varscan2
- CDH9 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50250776, COSV50334530; called by muse, mutect2, varscan2
- CLSTN2 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs1380076789, COSV71717618; called by muse, mutect2
- CMTR2 | c.979C>T p.H327Y | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV57602383; called by muse, mutect2, varscan2
- CNTNAP2 | c.1011G>A p.M337I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.097); catalogued as COSV62140539, COSV62240741; called by muse, mutect2
- COL11A2 | c.3247G>A p.D1083N (on ENST00000341947 / NM_080680.3; = p.D976N on NM_080679.2) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59493092; called by muse, mutect2, varscan2
- COL12A1 | c.9113C>T p.P3038L | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV59388548; called by muse, mutect2, varscan2
- COL4A6 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.254); catalogued as COSV57858362; called by muse, mutect2
- COX5B | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99300248; called by muse, mutect2, varscan2
- CSMD2 | c.8122G>A p.E2708K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.734); catalogued as COSV53874562; called by muse, mutect2
- CXXC5 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV100210636; called by muse, mutect2
- CYP2C19 | c.695A>G p.K232R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV64906631; called by muse, mutect2
- CYP4X1 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV64149552; called by mutect2, varscan2
- DEUP1 | c.1691T>A p.L564Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV53209262; called by muse, mutect2, varscan2
- DNAH11 | c.13025C>T p.P4342L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV60937160; called by muse, mutect2, varscan2
- DNAH2 | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV50013140; called by muse, mutect2, varscan2
- DPH2 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.185); catalogued as COSV99356370; called by muse, mutect2, varscan2
- DPH2 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.196); catalogued as COSV99356371; called by muse, mutect2, varscan2
- DRGX | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV65135685; called by muse, mutect2, varscan2
- DSP | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs769054351, COSV101131503, COSV65790792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DVL2 | c.1408C>G p.P470A | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV50034509; called by muse, mutect2
- ECE1 | c.248G>T p.C83F | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.62); catalogued as COSV51660529, COSV51666302; called by muse, mutect2, varscan2
- EGFL6 | c.1352T>G p.L451R | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63632672; called by muse, mutect2, varscan2
- ELAPOR2 | c.1931C>T p.S644F (on ENST00000450689 / NM_001142749.3; = p.S477F on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as rs747916801, COSV51883576; called by muse, mutect2, varscan2
- ENTHD1 | c.593-1G>A p.X198_splice | Splice Site (SNP) | VAF 4/50 reads (8%) | catalogued as COSV57316834; called by muse, mutect2
- EOMES | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV55410656; called by muse, mutect2, varscan2
- EP300 | c.5482C>T p.L1828F | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54325035; called by muse, mutect2, varscan2
- EPHB2 | c.2955+5G>A | Splice Region (SNP) | VAF 9/53 reads (17%) | catalogued as COSV101006873; called by muse, mutect2, varscan2
- FAM83A | c.649-1G>A p.X217_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV52683483; called by muse, varscan2
- FAT2 | c.1045G>A p.G349S | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.024); catalogued as COSV55812319; called by muse, mutect2, varscan2
- FCAR | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV62028087; called by muse, mutect2, varscan2
- FGR | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs866819600, COSV64969156; called by muse, mutect2, varscan2
- FHOD1 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.29); catalogued as COSV50758515; called by muse, mutect2, varscan2
- FNBP1 | c.1172T>G p.L391R | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV63085043; called by muse, mutect2
- FNDC3A | c.2654C>T p.P885L (on ENST00000492622 / NM_001079673.2; = p.P829L on NM_014923.5) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68132133; called by muse, mutect2
- FOXF1 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV99296434; called by muse, mutect2, varscan2
- FRAS1 | c.3508T>G p.W1170G | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV53586188; called by muse, mutect2, varscan2
- FSD2 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.154); catalogued as COSV58008400; called by muse, mutect2
- GALNT17 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1563076403, COSV61145704; called by muse, mutect2, varscan2
- GAPVD1 | c.1634A>C p.Q545P | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.888); catalogued as COSV52919687; called by muse, mutect2
- GDF2 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs782015913; called by muse, mutect2, varscan2
- GPR63 | c.609G>A p.W203* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV57739381, COSV57740691; called by muse, mutect2, varscan2
- GREB1 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.311); catalogued as COSV52179305; called by muse, mutect2
- H3-5 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV61186642; called by muse, mutect2, varscan2
- HCFC1 | c.4433C>T p.S1478F | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as COSV60069010; called by muse, mutect2, varscan2
- HDAC9 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV101286198; called by muse, mutect2
- HTR1A | c.305G>A p.W102* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as rs1175917615, COSV60499659; called by muse, mutect2, varscan2
- HYAL4 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as rs1245769231, COSV56137415; called by muse, mutect2, varscan2
- ICAM2 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV56742925; called by muse, mutect2, varscan2
- ICE1 | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56818219; called by muse, mutect2, varscan2
- IGF2R | c.6728C>T p.T2243I | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV63482111; called by muse, mutect2, varscan2
- IGKV1D-16 | c.319A>G p.T107A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1269470538; called by mutect2, varscan2
- IGSF9B | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as rs1283191535, COSV58063507; called by muse, mutect2
- ILDR1 | c.1072C>T p.P358S (on ENST00000344209 / NM_001199799.2; = p.P314S on NM_175924.4) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56546926; called by muse, mutect2, varscan2
- IQCF1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 48/321 reads (15%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as COSV58823020; called by muse, mutect2, varscan2
- ITFG1 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV57743370; called by muse, mutect2, varscan2
- ITGAL | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV63319871; called by muse, mutect2, varscan2
- JAKMIP2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54596748; called by muse, mutect2, varscan2
- KAT14 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.22); catalogued as COSV100890048; called by muse, mutect2
- KCNB2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV73049978; called by muse, mutect2, varscan2
- KCNJ9 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as COSV63631403; called by muse, mutect2, varscan2
- KLC1 | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55805302; called by muse, mutect2
- KLC1 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55805321; called by muse, mutect2
- KMT2D | c.8906C>T p.S2969L | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as rs762096305, COSV56407384; called by muse, mutect2, varscan2
- KMT2D | c.6902C>T p.P2301L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs1565794840, COSV99979422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KMT2D | c.6901C>T p.P2301S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.444); catalogued as rs200681496; ClinVar: not provided; called by muse, mutect2, varscan2
- KRTAP10-8 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555931154, COSV58165797; called by muse, mutect2, varscan2
- LAMA3 | c.1112T>C p.V371A | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV58061506; called by muse, mutect2
- LEXM | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV100827547; called by muse, mutect2, varscan2
- LEXM | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.022); catalogued as COSV100827548; called by muse, mutect2, varscan2
- LILRA5 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV56641318; called by muse, mutect2, varscan2
- LILRB1 | c.2101C>T p.H701Y (on ENST00000427581; = p.H650Y on NM_006669.6) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61115665; called by muse, mutect2, varscan2
- LLGL2 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51341628; called by muse, mutect2, varscan2
- LMNB2 | c.1387C>T p.H463Y | Missense Mutation (SNP) | VAF 51/480 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as COSV57586131; called by muse, mutect2, varscan2
- LPCAT1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV99358880; called by muse, mutect2, varscan2
- LRRC37A3 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.331); catalogued as rs540528768; called by muse, mutect2, varscan2
- LRRC74A | c.849G>A p.M283I | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV53607594; called by muse, mutect2
- LRRN2 | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1253809357, COSV65783168; called by muse, mutect2, varscan2
- MAGEB16 | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV67873472; called by muse, mutect2
- MDC1 | c.4102C>T p.P1368S | Missense Mutation (SNP) | VAF 24/337 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV64522940; called by muse, mutect2
- MDN1 | c.10477C>T p.P3493S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV65516349; called by muse, mutect2, varscan2
- MMD2 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758861281, COSV68660348; called by muse, mutect2, varscan2
- MPEG1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as rs377026755; called by mutect2, varscan2
- MUC16 | c.24431G>A p.G8144E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.007); catalogued as COSV67441078; called by muse, mutect2
- MYBPC2 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV63092994; called by muse, mutect2, varscan2
- MYBPC3 | c.2070G>A p.G690= | Splice Region (SNP) | VAF 26/188 reads (14%) | catalogued as COSV57022308; called by muse, mutect2, varscan2
- MYCBPAP | c.2021G>A p.R674K | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.02); catalogued as COSV60405254; called by muse, mutect2, varscan2
- MYH2 | c.1895G>A p.G632E | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV55430786; called by muse, mutect2, varscan2
- MYH4 | c.4877T>C p.L1626P | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55111305; called by muse, mutect2, varscan2
- MYO18B | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.79); catalogued as COSV59124228; called by muse, mutect2, varscan2
- MYO9B | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772454469, COSV68276649; called by muse, mutect2, varscan2
- MYOM2 | c.4184T>C p.V1395A | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV50701802; called by muse, mutect2, varscan2
- NELL2 | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV61568085; called by muse, mutect2, varscan2
- NEURL3 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60440450; called by muse, mutect2
- NID1 | c.2873C>T p.P958L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs771956305, COSV99937297; called by muse, mutect2, varscan2
- NOTCH4 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 70/606 reads (12%) | catalogued as rs745974502, COSV100900559; called by muse, mutect2, varscan2
- NPAP1 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as rs866413377, COSV61503908, COSV61505760; called by muse, mutect2, varscan2
- NPAS4 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); catalogued as COSV60648650; called by muse, mutect2
- NPHS1 | c.2795A>G p.N932S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV62286110; called by muse, mutect2, varscan2
- NRIP1 | c.3002C>T p.S1001L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as COSV59656768; called by mutect2, varscan2
- NSRP1 | c.1381A>G p.R461G | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV55932813; called by muse, mutect2
- NUCB1 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.058); catalogued as COSV54384841; called by muse, mutect2, varscan2
- NUMA1 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs773373258, COSV61182835; called by muse, mutect2, varscan2
- OR2A25 | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 25/145 reads (17%) | catalogued as rs866944696, COSV68716818; called by muse, mutect2, varscan2
- OR52M1 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV64171329; called by muse, mutect2, varscan2
- OR6T1 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV58305497; called by muse, mutect2, varscan2
- OR8H3 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV57907211; called by muse, mutect2, varscan2
- OSMR | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV57080418; called by muse, mutect2, varscan2
- OXR1 | c.640T>A p.F214I (on ENST00000442977 / NM_001198532.1; = p.F213I on NM_018002.3) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56323416; called by muse, mutect2, varscan2
- PCDHB14 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.176); catalogued as COSV53386204; called by muse, mutect2
- PCDHGA6 | c.2383C>T p.Q795* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | catalogued as COSV53892242; called by muse, mutect2
- PCYOX1 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV52475381; called by muse, mutect2
- PDZD2 | c.3222G>A p.W1074* | Nonsense Mutation (SNP) | VAF 24/166 reads (14%) | catalogued as COSV56848913; called by muse, mutect2, varscan2
- PGLYRP4 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62834456; called by muse, mutect2, varscan2
- PHF20L1 | c.2939G>A p.G980E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55188128; called by muse, mutect2, varscan2
- PHKA2 | c.2806G>A p.G936R | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1359913477, COSV66052123; called by muse, mutect2, varscan2
- PLA2G2F | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.045); catalogued as COSV100907901; called by muse, mutect2, varscan2
- PLCD3 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59558320; called by muse, mutect2, varscan2
- PLXNA3 | c.4555C>T p.P1519S | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63753006; called by muse, mutect2, varscan2
- PNPLA6 | c.4072C>T p.L1358F (on ENST00000414982 / NM_001166111.2; = p.L1310F on NM_006702.5) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55372870, COSV55375569; called by muse, mutect2, varscan2
- POLA1 | c.3850C>T p.P1284S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.95); catalogued as COSV66883299; called by muse, mutect2, varscan2
- POLR2A | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59488843; called by muse, mutect2
- POSTN | c.2486G>A p.R829Q | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); catalogued as rs1251739508, COSV65711698; called by muse, mutect2, varscan2
- PRDM15 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV54148224; called by muse, mutect2
- PRDX2 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56877196; called by muse, mutect2, varscan2
- PRKAA2 | c.1056G>A p.M352I | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV64801684; called by muse, mutect2, varscan2
- PRKAA2 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV64801704; called by muse, mutect2
- PRR5L | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61119669, COSV61123460; called by muse, mutect2, varscan2
- PSD4 | c.1909C>T p.R637* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as COSV55524310, COSV99830929; called by muse, mutect2
- PSG4 | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54932404, COSV54941410; called by muse, mutect2, varscan2
- PSG5 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs948717445, COSV61653363; called by muse, mutect2, varscan2
- PSG6 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.049); catalogued as COSV51829643; called by muse, mutect2, varscan2
- PTGFR | c.392T>A p.I131N | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV66114127; called by muse, mutect2, varscan2
- PTPRM | c.3404T>G p.V1135G | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59842069; called by muse, mutect2, varscan2
- PYGO1 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57346362; called by muse, mutect2, varscan2
- RAD1 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as COSV57714763; called by muse, varscan2
- RALGAPB | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV53433947; called by muse, mutect2, varscan2
- RBFOX1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); catalogued as rs1064796313, COSV100302880, COSV60943286; ClinVar: uncertain significance; called by muse, mutect2
- RBM10 | c.645G>C p.E215D | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100237519, COSV61307552; called by muse, mutect2, varscan2
- RBM10 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV61307559; called by muse, mutect2, varscan2
- RBM15B | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs782659835, COSV60370940; called by muse, mutect2, varscan2
- RCAN1 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 85/829 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs527504893, COSV58248575; called by muse, mutect2, varscan2
- REST | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 36/304 reads (12%) | catalogued as COSV100470828; called by muse, mutect2, varscan2
- RGS12 | c.2363C>T p.A788V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV100122739; called by muse, mutect2
- RNASEL | c.1380T>A p.F460L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.596); catalogued as COSV62376124; called by muse, mutect2, varscan2
- ROBO2 | c.3878G>A p.G1293E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59893842; called by muse, mutect2
- RRP8 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV54448693; called by muse, mutect2, varscan2
- SEH1L | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV50816168; called by muse, mutect2, varscan2
- SELENOV | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1252506506, COSV59063155; called by muse, mutect2
- SEPTIN14 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66425797, COSV66429804; called by muse, mutect2, varscan2
- SFXN5 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.057); catalogued as COSV50247703; called by muse, mutect2
- SH3BP2 | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV62553450; called by muse, mutect2, varscan2
- SH3TC1 | c.629-1G>A p.X210_splice | Splice Site (SNP) | VAF 18/102 reads (18%) | catalogued as COSV55280750; called by muse, mutect2, varscan2
- SIGLEC10 | c.265C>G p.R89G | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59478411; called by muse, mutect2, varscan2
- SIPA1L3 | c.3617G>A p.G1206D | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.079); catalogued as rs1218434529, COSV55908198; called by mutect2, varscan2
- SLA2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs372541692, COSV53409940; called by muse, mutect2, varscan2
- SLC5A6 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.074); catalogued as COSV60158242; called by muse, varscan2
- SLC6A11 | c.1070G>A p.G357D | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54389363; called by muse, mutect2, varscan2
- SLCO2B1 | c.1733C>T p.T578I | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV56932636; called by muse, mutect2, varscan2
- SLF1 | c.2021C>T p.S674F | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54367165; called by muse, mutect2
- SPAG17 | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs982562781, COSV60459312; called by muse, mutect2, varscan2
- SPATA31E1 | c.3928G>A p.D1310N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.961); catalogued as rs773616022, COSV57789312; called by mutect2, varscan2
- SPRR1A | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as rs767491967, COSV61080883; called by muse, mutect2, varscan2
- SPSB4 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60144533; called by muse, mutect2
- SRGAP3 | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs146672079, COSV64529943; called by mutect2, varscan2
- SSTR5 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53511208; called by muse, mutect2, varscan2
- ST18 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV52483136, COSV52507618; called by mutect2, varscan2
- STRADA | c.940C>T p.P314S (on ENST00000336174 / NM_001363786.1; = p.P277S on NM_153335.6) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.04); catalogued as rs1467387694, COSV51990983; called by mutect2, varscan2
- SUN5 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.284); catalogued as COSV62179941; called by muse, mutect2, varscan2
- TAF1 | c.905C>T p.S302F (on ENST00000373790 / NM_138923.4; = p.S323F on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV52106254; called by muse, mutect2
- TAF1L | c.4498C>T p.L1500F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.153); catalogued as COSV54256322; called by muse, mutect2, varscan2
- TAFA1 | c.41G>A p.W14* | Nonsense Mutation (SNP) | VAF 18/189 reads (10%) | catalogued as COSV72036807; called by muse, mutect2, varscan2
- TDRD5 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | catalogued as COSV54238354; called by mutect2, varscan2
- TECTA | c.3992C>T p.S1331F | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV50687599; called by muse, mutect2, varscan2
- TECTA | c.6050C>T p.S2017F | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM165474, COSV50687600; called by muse, mutect2, varscan2
- TEKT3 | c.601C>T p.H201Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV58625717; called by muse, mutect2, varscan2
- TENM4 | c.8170G>A p.E2724K | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99572869; called by muse, mutect2, varscan2
- TGM5 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); catalogued as rs1209114689, COSV55008320; called by muse, mutect2
- THADA | c.4864C>T p.Q1622* | Nonsense Mutation (SNP) | VAF 30/498 reads (6%) | catalogued as COSV100368284; called by muse, mutect2
- TKTL2 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs868457119, COSV54917146; called by muse, mutect2, varscan2
- TP73 | c.307A>G p.S103G | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV60698018; called by muse, mutect2, varscan2
- TPP2 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs773244873, COSV65750679; called by mutect2, varscan2
- TRPM5 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 45/366 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs749308848, COSV50144203; called by muse, mutect2, varscan2
- TSPYL6 | c.659A>T p.D220V | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57811577; called by muse, mutect2
- TTBK2 | c.2896G>A p.E966K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs866877821, COSV51157163; called by muse, mutect2, varscan2
- TTPAL | c.11A>C p.E4A | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV52828200; called by muse, varscan2
- TUBAL3 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100990498; called by muse, mutect2
- TUBAL3 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100990499; called by muse, mutect2
- UBA7 | c.1306C>T p.L436F | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV61091179; called by muse, mutect2
- USH1C | c.1153C>T p.L385F | Missense Mutation (SNP) | VAF 75/572 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV50013897; called by muse, mutect2, varscan2
- USP26 | c.1091T>C p.L364P | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV63707951; called by muse, mutect2
- VAV2 | c.1756G>A p.G586R (on ENST00000371850 / NM_001134398.2; = p.G576R on NM_003371.4) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV64080019; called by muse, mutect2, varscan2
- VCX3B | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1223217141, COSV101123776; called by muse, mutect2
- VPS13D | c.9847C>T p.P3283S | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1460872061, COSV50621071, COSV50623012, COSV50623248; called by muse, mutect2, varscan2
- VPS36 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100955163; called by mutect2, varscan2
- VSTM1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as rs780676695, COSV58073688; called by muse, mutect2, varscan2
- WDR72 | c.1011C>A p.Y337* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV64741062; called by muse, mutect2, varscan2
- WSCD2 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV54577201, COSV54585482; called by muse, mutect2, varscan2
- WWC3 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.531); catalogued as COSV66501232; called by muse, mutect2, varscan2
- YIPF3 | c.189C>A p.D63E | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58303381; called by muse, mutect2, varscan2
- ZBTB9 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV67701754; called by muse, mutect2
- ZEB1 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58035498, COSV58039665; called by muse, mutect2, varscan2
- ZFHX4 | c.7681C>T p.P2561S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.054); catalogued as COSV50478869, COSV51505684; called by muse, mutect2, varscan2
- ZNF174 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 28/304 reads (9%) | catalogued as COSV51901897; called by muse, mutect2
- ZNF569 | c.551C>A p.T184N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV100386654, COSV57593290; called by muse, mutect2, varscan2
- ZNF862 | c.1382G>A p.R461K | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as COSV56222506, COSV56227032; called by muse, mutect2, varscan2
- AATF | c.1203G>T p.M401I | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- AATF | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ARHGAP31 | c.502_527del p.R168Kfs*6 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | called by mutect2, pindel
- NUP98 | c.4870_4872dup p.A1624dup (on ENST00000359171 / NM_001365126.1; = p.A1607dup on NM_016320.5 and 4 other RefSeq transcripts) | In Frame Ins (INS) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- SEC24C | c.23del p.P8Hfs*219 | Frame Shift Del (DEL) | VAF 13/95 reads (14%) | called by mutect2, pindel, varscan2
- ABCC1 | c.3504C>T p.F1168= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs372721973; called by muse, mutect2, varscan2
- ABCC10 | c.1464C>T p.C488= (on ENST00000372530 / NM_001198934.2; = p.C445= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/224 reads (26%) | catalogued as rs1235932936, COSV55084079; called by muse, mutect2, varscan2
- AC004922.1 | c.189G>A p.K63= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV53555314; called by muse, mutect2, varscan2
- ACAN | c.5928G>A p.G1976= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV61355076; called by muse, mutect2, varscan2
- ADAM18 | c.1965C>T p.F655= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV55843213; called by muse, mutect2, varscan2
- ADAM33 | c.1501C>T p.L501= | Silent (SNP) | VAF 20/176 reads (11%) | catalogued as COSV62933435; called by muse, mutect2
- AMIGO1 | c.504C>T p.N168= | Silent (SNP) | VAF 22/278 reads (8%) | catalogued as rs1239874615, COSV100880999; called by muse, mutect2
- AMPD1 | c.1548C>T p.F516= | Silent (SNP) | VAF 43/148 reads (29%) | catalogued as COSV62414881; called by muse, mutect2, varscan2
- ANK1 | c.4038G>A p.A1346= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as rs199719745, COSV55871447, COSV55882516; called by muse, mutect2, varscan2
- AOC1 | c.1830G>A p.Q610= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV62866629; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.333C>T p.F111= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as COSV63436909; called by muse, mutect2, varscan2
- ATP2B4 | c.1887C>T p.P629= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV58173867; called by muse, mutect2, varscan2
- CA6 | c.495C>T p.F165= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as rs1366948886, COSV66261367; called by muse, mutect2, varscan2
- CACNA1H | c.4125C>T p.S1375= | Silent (SNP) | VAF 19/186 reads (10%) | catalogued as rs1357310736, COSV61982572; called by muse, mutect2, varscan2
- CALCA | c.9C>T p.F3= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV59027377; called by muse, mutect2, varscan2
- CAP2 | c.741C>T p.F247= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs150167032; called by muse, mutect2, varscan2
- CATSPER1 | c.543C>T p.P181= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as rs762457852, COSV56408722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD1E | c.24C>T p.F8= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs376989417, COSV63772615; called by mutect2, varscan2
- CDH15 | c.1182G>A p.V394= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1246771373, COSV57021621; called by muse, mutect2
- CENPB | c.925C>T p.L309= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV60144089; called by muse, mutect2
- CEP43 | c.885C>T p.S295= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV62760346; called by muse, mutect2, varscan2
- CLDN18 | c.366G>A p.G122= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV51735639; called by muse, mutect2, varscan2
- COPG2 | c.699C>T p.I233= | Silent (SNP) | VAF 52/246 reads (21%) | catalogued as COSV58404056; called by muse, mutect2, varscan2
- COX5B | c.339C>T p.C113= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV99300247; called by muse, mutect2, varscan2
- CYP4F22 | c.345C>T p.I115= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as COSV99512665; called by muse, mutect2
- D2HGDH | c.849C>T p.F283= | Silent (SNP) | VAF 27/234 reads (12%) | catalogued as COSV58318831; called by muse, mutect2, varscan2
- DDN | c.2124G>A p.R708= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV70404039; called by muse, mutect2, varscan2
- DEFB118 | c.9C>T p.L3= | Silent (SNP) | VAF 10/121 reads (8%) | catalogued as COSV53619467; called by muse, mutect2
- DHRS2 | c.174G>A p.R58= | Silent (SNP) | VAF 40/234 reads (17%) | catalogued as COSV51630240; called by muse, mutect2, varscan2
- DNAH17 | c.2209C>T p.L737= | Silent (SNP) | VAF 30/238 reads (13%) | catalogued as COSV67749148, COSV67753943; called by muse, mutect2, varscan2
- DNAJC7 | c.48G>A p.P16= | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as rs201630112, COSV56917317; called by muse, mutect2
- DRD5 | c.363C>T p.I121= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV58576576; called by muse, mutect2, varscan2
- DUOX2 | c.4144T>C p.L1382= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as rs1260812445, COSV66530368; called by muse, mutect2, varscan2
- ENC1 | c.894C>T p.F298= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV56628494; called by muse, mutect2, varscan2
- EXOSC5 | c.213C>T p.F71= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as rs750069576, COSV54195336; called by muse, mutect2, varscan2
- F11 | c.213C>T p.T71= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as COSV53003972; called by muse, mutect2
- F2RL2 | c.360C>T p.F120= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV56969659; called by muse, mutect2, varscan2
- FAM83G | c.1902A>T p.S634= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs773273233, COSV58754986; called by muse, mutect2, varscan2
- FBRS | c.228C>T p.F76= (on ENST00000287468; = p.F596= on NM_001105079.3) | Silent (SNP) | VAF 18/173 reads (10%) | catalogued as COSV54914608; called by muse, mutect2, varscan2
- FBXO24 | c.1725C>T p.P575= (on ENST00000241071 / NM_033506.3; = p.P613= on NM_012172.5) | Silent (SNP) | VAF 25/115 reads (22%) | catalogued as COSV53823331; called by muse, mutect2, varscan2
- FLG | c.11085C>T p.S3695= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as COSV100911359; called by muse, mutect2
- FOXF1 | c.1026G>A p.K342= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs199981852, COSV99296431, COSV99296537; called by muse, mutect2, varscan2
- FZD10 | c.1107C>T p.I369= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV57471906; called by muse, mutect2, varscan2
- GABRE | c.993C>T p.F331= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV64818769; called by muse, mutect2, varscan2
- GCNA | c.498G>A p.S166= | Silent (SNP) | VAF 20/174 reads (11%) | catalogued as rs113212495; called by muse, mutect2, varscan2
- GDF5 | c.1332G>A p.T444= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs529197082, COSV65499041; called by muse, mutect2, varscan2
- GFRA2 | c.75C>T p.S25= | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- GGCX | c.1605C>T p.F535= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as COSV52086940; called by muse, mutect2, varscan2
- GGTLC2 | c.270G>A p.G90= | Silent (SNP) | VAF 24/209 reads (11%) | catalogued as rs1424150548, COSV67853769; called by muse, mutect2, varscan2
- HCRTR1 | c.174C>T p.V58= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as rs201881922, COSV65484596; called by muse, mutect2
- HEPACAM | c.270C>T p.T90= | Silent (SNP) | VAF 17/135 reads (13%) | catalogued as rs774642930, COSV100005996, COSV53428396; called by muse, mutect2, varscan2
- HIF3A | c.1530G>A p.R510= (on ENST00000377670 / NM_152795.4; = p.R441= on NM_022462.4) | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as COSV52195405; called by muse, mutect2, varscan2
- IL10RA | c.1053G>A p.R351= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs1255893000, COSV57139317; called by muse, mutect2, varscan2
- INTS6 | c.1692G>A p.L564= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV60876008; called by mutect2, varscan2
- ITGA2B | c.2964G>A p.R988= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV52230906; called by muse, mutect2
- JPH2 | c.1152C>T p.A384= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs1487904026, COSV65901606; called by muse, mutect2
- KANK4 | c.1362C>T p.L454= | Silent (SNP) | VAF 37/240 reads (15%) | catalogued as COSV62985218; called by muse, mutect2, varscan2
- KCNA5 | c.577C>T p.L193= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs996977898, COSV52903606; called by muse, mutect2, varscan2
- KCNB2 | c.57C>T p.S19= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV101578717; called by muse, mutect2, varscan2
- KCNQ5 | c.2118C>T p.S706= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV100571757; called by muse, mutect2, varscan2
- KCNS3 | c.21C>T p.F7= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV58405059; called by muse, mutect2, varscan2
- KCTD13 | c.678C>T p.F226= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV58156344; called by muse, mutect2
- KIRREL1 | c.1182C>T p.I394= | Silent (SNP) | VAF 20/159 reads (13%) | catalogued as COSV63285007; called by muse, mutect2, varscan2
- KLC4 | c.432G>A p.K144= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV99431630; called by muse, mutect2
- LPCAT1 | c.957G>A p.A319= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs768432015, COSV99358883, COSV99358925; called by muse, mutect2, varscan2
- LRTM1 | c.672C>T p.I224= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV55510045; called by muse, mutect2, varscan2
- MAGED1 | c.1923G>A p.E641= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV58514342; called by muse, mutect2, varscan2
- MAN2C1 | c.882C>T p.I294= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV51226378; called by muse, mutect2, varscan2
- MAPK4 | c.231C>T p.I77= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV68540994; called by muse, mutect2, varscan2
- MED13L | c.4383T>G p.R1461= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV56115133; called by muse, mutect2, varscan2
- MICAL3 | c.2577C>T p.A859= | Silent (SNP) | VAF 19/159 reads (12%) | catalogued as rs779230828, COSV52891642; called by muse, mutect2, varscan2
- MRPL38 | c.1032C>T p.F344= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs775410424, COSV53932134; called by muse, mutect2, varscan2
- MUC16 | c.4641G>A p.V1547= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV67441098; called by muse, mutect2
- MUC17 | c.279G>A p.S93= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs1473027015, COSV60279043; called by muse, mutect2, varscan2
- MYO19 | c.2256T>G p.L752= (on ENST00000614623 / NM_001163735.1; = p.L552= on NM_025109.5) | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- NEB | c.3579G>A p.K1193= | Silent (SNP) | VAF 18/185 reads (10%) | catalogued as COSV50805901; called by muse, mutect2
- NID1 | c.2874C>T p.P958= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs372553525; called by mutect2, varscan2
- NLRP7 | c.549G>A p.G183= | Silent (SNP) | VAF 20/167 reads (12%) | catalogued as COSV60170588; called by muse, mutect2, varscan2
- NOTCH4 | c.405C>T p.I135= | Silent (SNP) | VAF 72/615 reads (12%) | catalogued as COSV100900560; called by muse, mutect2, varscan2
- NRK | c.3195C>T p.V1065= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV54588739; called by muse, mutect2
- NRXN1 | c.1740C>T p.F580= | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as COSV58434297; called by muse, mutect2, varscan2
- OR13C9 | c.306C>T p.F102= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99403398; called by muse, mutect2, varscan2
- OR4D1 | c.129C>T p.L43= | Silent (SNP) | VAF 22/256 reads (9%) | catalogued as COSV52124335; called by muse, mutect2
- OR52B6 | c.681C>T p.G227= | Silent (SNP) | VAF 37/249 reads (15%) | catalogued as COSV61447124; called by muse, mutect2, varscan2
- OR5D14 | c.477G>A p.L159= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV59455226; called by muse, mutect2, varscan2
- OR8H3 | c.705G>A p.Q235= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100538744, COSV57907222, COSV57907840; called by muse, mutect2
- PAX4 | c.486C>T p.P162= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV58387073; called by muse, mutect2, varscan2
- PCDHB3 | c.348C>T p.F116= | Silent (SNP) | VAF 13/134 reads (10%) | catalogued as rs943294647, COSV50563888, COSV50569842; called by muse, mutect2
- PCDHB4 | c.1677C>T p.F559= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs553336245, COSV52022887; called by muse, mutect2, varscan2
- PCDHGA3 | c.2127C>T p.I709= | Silent (SNP) | VAF 36/210 reads (17%) | catalogued as rs1237874036, COSV53892224, COSV53965517; called by muse, mutect2, varscan2
- PGS1 | c.709C>T p.L237= | Silent (SNP) | VAF 23/214 reads (11%) | catalogued as COSV53143059; called by muse, mutect2, varscan2
- PIM1 | c.225C>T p.S75= | Silent (SNP) | VAF 27/180 reads (15%) | catalogued as COSV65164428; called by muse, mutect2, varscan2
- PLA2G2F | c.582C>T p.P194= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs1331643659, COSV100907900; called by muse, mutect2, varscan2
- PLD2 | c.2151C>T p.I717= | Silent (SNP) | VAF 20/203 reads (10%) | catalogued as COSV54003098; called by muse, mutect2
- PLEKHG4B | c.2067G>A p.G689= (on ENST00000283426; = p.G1045= on NM_052909.5) | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1262781563, COSV52042834; called by muse, mutect2
- PNMA5 | c.471G>A p.R157= | Silent (SNP) | VAF 29/293 reads (10%) | catalogued as rs1556924465, COSV62625308; called by muse, mutect2, varscan2
- PPFIA2 | c.75G>A p.S25= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs767226421, COSV61018804; called by mutect2, varscan2
- PRAMEF10 | c.876G>A p.K292= | Silent (SNP) | VAF 18/298 reads (6%) | called by muse, mutect2
- PRDM4 | c.274C>T p.L92= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV99946489; called by muse, mutect2
- PRDM4 | c.273C>T p.T91= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs1177583593, COSV99946490; called by muse, mutect2
- PRRC2C | c.7614C>T p.S2538= (on ENST00000367742; = p.S2536= on NM_015172.4) | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV58900172; called by muse, mutect2, varscan2
- PRRG3 | c.36G>A p.S12= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs1367218668, COSV64850629; called by muse, mutect2, varscan2
- PRSS22 | c.207G>A p.K69= | Silent (SNP) | VAF 11/121 reads (9%) | catalogued as COSV50720852; called by muse, mutect2, varscan2
- PRUNE2 | c.6987G>A p.P2329= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs150789659; called by muse, mutect2, varscan2
- PTPN14 | c.726G>A p.R242= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs371149099; called by muse, mutect2, varscan2
- RAD1 | c.474G>T p.L158= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV57714781; called by muse, varscan2
- RASAL3 | c.2970G>A p.R990= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as COSV54604218; called by muse, mutect2, varscan2
- REST | c.2268C>T p.V756= | Silent (SNP) | VAF 37/305 reads (12%) | catalogued as COSV100470827; called by muse, mutect2, varscan2
- RRBP1 | c.3318C>T p.P1106= (on ENST00000377813 / NM_001365613.2; = p.P673= on NM_004587.3) | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- RUVBL2 | c.945C>T p.A315= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99668916; called by muse, mutect2, varscan2
- RUVBL2 | c.946C>T p.L316= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV99668918; called by muse, mutect2, varscan2
- SACS | c.11139C>T p.P3713= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV66533198; called by muse, mutect2
- SDS | c.466C>T p.L156= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV57452450; called by muse, mutect2, varscan2
- SHH | c.159G>A p.E53= | Silent (SNP) | VAF 117/485 reads (24%) | catalogued as COSV51918181; called by muse, mutect2, varscan2
- SLC17A1 | c.1380A>G p.K460= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV55076907; called by muse, mutect2, varscan2
- SLC38A10 | c.2127G>A p.Q709= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs775605554, COSV99917332; called by muse, mutect2, varscan2
- SLC43A2 | c.786C>T p.F262= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as rs12936338, COSV56767540; called by muse, mutect2, varscan2
- SLC6A20 | c.156C>T p.I52= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs761532331, COSV62069935; called by muse, mutect2, varscan2
- SLC7A4 | c.1125G>A p.G375= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs773320175, COSV60382223; called by mutect2, varscan2
- SLCO1B1 | c.1596G>A p.R532= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV57006517; called by muse, mutect2, varscan2
- SLITRK1 | c.930G>A p.K310= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV104425249, COSV65673976; called by muse, mutect2, varscan2
- SORCS3 | c.2031C>T p.L677= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV63793110; called by muse, mutect2
- STIM1 | c.1702C>T p.L568= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV56151092; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3400C>T p.L1134= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV59125550; called by muse, mutect2, varscan2
- SYNPO2 | c.2388C>T p.N796= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV61105715; called by muse, mutect2, varscan2
- TCFL5 | c.1275C>T p.L425= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV53895345; called by muse, mutect2
- TENM1 | c.3144G>A p.T1048= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs763660900, COSV64424110; called by muse, mutect2, varscan2
- TENM4 | c.8169G>A p.G2723= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as COSV99572870; called by muse, mutect2, varscan2
- THADA | c.4863C>T p.P1621= | Silent (SNP) | VAF 28/494 reads (6%) | catalogued as COSV100368285; called by muse, mutect2
- TKT | c.1260C>T p.S420= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV56244223; called by muse, mutect2, varscan2
- TMPRSS3 | c.441C>T p.F147= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV52299638; called by muse, mutect2, varscan2
- TRAM1L1 | c.213C>T p.S71= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV60291082; called by muse, mutect2, varscan2
- TRIM14 | c.510G>A p.Q170= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs1220323452, COSV58353086; called by muse, mutect2, varscan2
- TRPM6 | c.621C>T p.I207= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs749287479, COSV62502142; called by mutect2, varscan2
- TRPV5 | c.1614C>G p.L538= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as COSV54682769; called by muse, mutect2, varscan2
- UGT3A2 | c.1404G>A p.A468= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs373801136; called by mutect2, varscan2
- USP39 | c.1122C>T p.L374= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV60380576; called by muse, mutect2
- WNT3A | c.519G>A p.R173= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as rs1171329855, COSV52728184; called by muse, mutect2, varscan2
- XPNPEP3 | c.1029C>T p.I343= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV63210039; called by muse, mutect2, varscan2
- ZBTB3 | c.1020G>A p.Q340= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV67360797; called by muse, mutect2, varscan2
- ZBTB40 | c.1917G>A p.P639= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs140676819; called by muse, mutect2, varscan2
- ZFP42 | c.708C>T p.F236= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV58816272; called by muse, mutect2, varscan2
- ZNF23 | c.1659C>T p.I553= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV61840419; called by muse, mutect2, varscan2
- ARIH2 | chr3:48918813 G>A | 5'Flank (SNP) | VAF 8/46 reads (17%) | catalogued as rs1485669855, COSV62703690; called by muse, mutect2, varscan2
- CDCA7 | c.147+649G>A | Intron (SNP) | VAF 7/60 reads (12%) | catalogued as COSV60719763; called by muse, mutect2, varscan2
- ELK1 | chrX:47650491 C>T | 5'Flank (SNP) | VAF 7/78 reads (9%) | catalogued as COSV99901971; called by muse, mutect2
- FAM193B | c.1275+972C>A | Intron (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100286489, COSV100286656; called by muse, mutect2
- LINC00174 | n.3236C>T | RNA (SNP) | VAF 6/28 reads (21%) | catalogued as rs930717200; called by muse, mutect2, varscan2
- LINC01559 | n.393C>T | RNA (SNP) | VAF 7/52 reads (13%) | catalogued as rs778776498; called by mutect2, varscan2
- MAGEA5 | n.64G>T | RNA (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.735C>T | RNA (SNP) | VAF 11/85 reads (13%) | catalogued as rs782728312; called by muse, mutect2, varscan2
- MIR527 | n.22G>A | RNA (SNP) | VAF 25/136 reads (18%) | catalogued as rs753483292; called by muse, mutect2, varscan2
- OR2U1P | n.411A>G | RNA (SNP) | VAF 17/100 reads (17%) | catalogued as rs1158504733; called by muse, mutect2, varscan2
- SEBOX | c.-91G>A | 5'UTR (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99412055; called by muse, mutect2, varscan2
- SEMA3E | c.*2G>A | 3'UTR (SNP) | VAF 44/259 reads (17%) | catalogued as COSV100318018; called by muse, mutect2, varscan2
- WASF4P | n.1065C>T | RNA (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
